Gene-level copy-number profile of tumor specimen TCGA-13-0792-01A from TCGA case TCGA-13-0792, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 40.3 years (14,729 days).
Specimen TCGA-13-0792-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7af29da0-5b60-4b08-9fed-074550dc5d1b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0792-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c842aed-4f70-40b9-9b9e-a3c860f355b5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 135; copy number 1: 4,622; copy number 2: 20,945; copy number 3: 22,544; copy number 4: 7,169; copy number 5: 2,618; copy number 6: 726; copy number 7: 625; copy number 8: 134; copy number 9: 49; copy number 10: 51; copy number 11: 153; copy number 13: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0792-01): tumor purity 0.81, ploidy 2.84, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 135 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:76,833,839–90,231,682, 135 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,059 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:82,806,515–87,793,629, 31 genes, copy number 7: CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P.
- chr5:58,198–4,440,259, 96 genes, copy number 7 (broad region; genes not listed).
- chr5:4,512,262–4,516,776, 1 gene, copy number 7: AC106799.1.
- chr8:65,161,145–71,228,629, 98 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:82,862,779–83,408,900, 6 genes, copy number 7: AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419.
- chr8:108,162,787–141,662,209, 387 genes, copy number 7–13 (broad region; genes not listed).
- chr12:2,603,350–6,820,799, 135 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr12:17,479,446–32,646,050, 265 genes, copy number 7–8 (broad region; genes not listed).
- chr12:41,188,320–42,590,355, 24 genes, copy number 7 (within-gene range 2–7): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3.
- chr12:64,451,591–64,881,033, 15 genes, copy number 7 (within-gene range 5–7): AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30.
- chr12:64,820,179–64,825,955, 1 gene, copy number 7: AC025262.3.

Autosomal genes at a single copy (total copy number 1): 4,204. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
